Somatic mutation profile of tumor specimen TCGA-98-A53A-01A (aliquot TCGA-98-A53A-01A-11D-A25L-08) from TCGA case TCGA-98-A53A, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.3 years (25,662 days).
Specimen TCGA-98-A53A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82e28629-0f98-41a5-a3d8-dd312c7693be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-98-A53A-10A (Blood Derived Normal), aliquot TCGA-98-A53A-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/add274d4-c869-40ae-9b39-f33f83809e34

The open-access MAF lists 349 somatic variants for this specimen: 267 protein-altering or splice-affecting, 72 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 72, Frame Shift Del 26, Nonsense Mutation 12, Splice Site 11, RNA 4, In Frame Del 3, Frame Shift Ins 3, Splice Region 2, Intron 2, 5'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MC2R | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs758709668, CM950793, COSV59618156, COSV59618264; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs539295465, COSV99435195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAK1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101276029; called by muse, mutect2, varscan2
- ABCA10 | c.3111C>G p.I1037M | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV99289212; called by muse, mutect2, varscan2
- ABRA | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 126/462 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV100357641; called by muse, mutect2, varscan2
- ADAMTS12 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100711556; called by muse, mutect2, varscan2
- ADGRG4 | c.3142C>A p.L1048I | Missense Mutation (SNP) | VAF 135/200 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99796428; called by muse, mutect2, varscan2
- ADNP | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV100823843; called by muse, mutect2, varscan2
- AGFG1 | c.1432G>C p.A478P | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.755); catalogued as rs1255936564, COSV100029119; called by muse, mutect2, varscan2
- AHNAK | c.5138C>T p.P1713L | Missense Mutation (SNP) | VAF 134/361 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99949156; called by muse, mutect2, varscan2
- ALDH1A2 | c.1485G>T p.M495I | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV51084322; called by muse, mutect2, varscan2
- ALDH5A1 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV62373143; called by muse, mutect2, varscan2
- ANKFN1 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100594041; called by muse, mutect2, varscan2
- ARHGAP31 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99957606; called by muse, mutect2, varscan2
- ARMC8 | c.777-1G>T p.X259_splice (on ENST00000469044 / NM_001363941.2; = p.X245_splice on NM_014154.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/170 reads (18%) | catalogued as COSV100627818; called by muse, mutect2, varscan2
- ASH1L | c.6555G>T p.R2185S (on ENST00000368346 / NM_001366177.2; = p.R2180S on NM_018489.3) | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100853572; called by muse, mutect2, varscan2
- ASTN1 | c.367C>G p.H123D | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV99920913, COSV99922787; called by muse, mutect2, varscan2
- ASXL2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV55465024; called by muse, mutect2, varscan2
- ATG7 | c.334-1G>A p.X112_splice | Splice Site (SNP) | VAF 92/174 reads (53%) | catalogued as COSV100607829, COSV61614347; called by muse, mutect2, varscan2
- ATP6V1G3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99811021; called by muse, mutect2, varscan2
- BCL6B | c.546del p.S183Vfs*20 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | catalogued as COSV53426596; called by pindel, varscan2
- BRCA1 | c.3770_3771del p.E1257Gfs*9 | Frame Shift Del (DEL) | VAF 73/259 reads (28%) | catalogued as rs80357579; called by pindel, varscan2
- BTNL3 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV100732242; called by muse, mutect2, varscan2
- C7 | c.2114G>A p.W705* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100496453; called by muse, mutect2, varscan2
- C8orf37 | c.243+2T>C p.X81_splice | Splice Site (SNP) | VAF 24/105 reads (23%) | catalogued as CS144873, COSV99713212; called by muse, mutect2, varscan2
- CAMTA2 | c.2398C>T p.R800W | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201373442, COSV61835453; called by muse, mutect2, varscan2
- CCDC181 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV100890375; called by muse, mutect2, varscan2
- CCDC63 | c.672-1G>T p.X224_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100370573, COSV57527695; called by muse, mutect2, varscan2
- CCS | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100040131; called by muse, mutect2, varscan2
- CDC42BPG | c.2061-1G>T p.X687_splice | Splice Site (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100712142, COSV61347051; called by muse, mutect2, varscan2
- CDH23 | c.2832del p.S944Rfs*45 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as COSV54944260; called by mutect2, pindel*, varscan2
- CFAP47 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as COSV99935690; called by muse, mutect2, varscan2
- CFHR2 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 50/189 reads (26%) | catalogued as COSV100804385; called by muse, mutect2, varscan2
- CLMN | c.1361A>G p.K454R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV54179164; called by muse, mutect2, varscan2
- CNKSR1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100836772, COSV64164399; called by muse, mutect2, varscan2
- CNPY2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as rs141635081; called by muse, mutect2, varscan2
- CNTF | c.471G>C p.W157C | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs750727405, COSV100284702, COSV60159941; called by muse, mutect2, varscan2
- CNTNAP5 | c.3058A>C p.K1020Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.957); catalogued as COSV101444000; called by muse, mutect2
- CNTNAP5 | c.3060G>C p.K1020N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV101443079, COSV101444001; called by muse, mutect2
- COL11A2 | c.3824C>A p.P1275H (on ENST00000341947 / NM_080680.3; = p.P1168H on NM_080679.2) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100554430; called by muse, mutect2, varscan2
- COL4A3 | c.1922A>T p.E641V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV101170509; called by muse, mutect2, varscan2
- CRACDL | c.2501G>C p.R834P | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101194122; called by muse, mutect2, varscan2
- CRYBB3 | c.420G>T p.W140C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99309172; called by muse, mutect2, varscan2
- CRYGB | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV99650009; called by muse, mutect2, varscan2
- CSE1L | c.1316C>G p.S439* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99522199; called by muse, mutect2, varscan2
- DCDC2 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101016832, COSV104428892; called by muse, mutect2, varscan2
- DCHS2 | n.5211G>T | Splice Region (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100602453; called by muse, mutect2, varscan2
- DMD | c.8597T>C p.L2866P | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100628877; called by muse, mutect2, varscan2
- DNAH9 | c.1518+2T>C p.X506_splice | Splice Site (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99307622; called by muse, mutect2, varscan2
- DPPA2 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 124/196 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV101524792; called by muse, mutect2, varscan2
- DPYD | c.2807G>T p.G936V | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100929305, COSV100929596; called by muse, mutect2, varscan2
- DSCAM | c.172T>A p.W58R | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101261331; called by muse, mutect2, varscan2
- DSCAML1 | c.4503G>T p.K1501N (on ENST00000321322; = p.K1441N on NM_020693.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV100356922; called by muse, mutect2, varscan2
- DYRK1B | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100546715; called by muse, mutect2, varscan2
- ECE1 | c.715_718del p.V239Mfs*13 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | catalogued as rs768241100; called by mutect2, pindel, varscan2
- EML2 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99840372; called by muse, mutect2, varscan2
- EOMES | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99842214; called by muse, mutect2, varscan2
- ESPL1 | c.6262C>T p.P2088S | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV99229686; called by muse, mutect2, varscan2
- ETAA1 | c.446_448del p.T149del | In Frame Del (DEL) | VAF 37/154 reads (24%) | catalogued as rs771249312; called by pindel, varscan2
- EZHIP | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100539867, COSV57954947, COSV57956805; called by muse, mutect2, varscan2
- FAM107B | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs763943353, COSV51681273; called by muse, mutect2, varscan2
- FAM135B | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746930192, COSV52724669; called by muse, varscan2
- FAM135B | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs769546810, COSV52755033; called by muse, varscan2
- FAM237A | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV101405595; called by muse, mutect2, varscan2
- FAM47A | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as COSV100650029; called by muse, mutect2, varscan2
- FAT4 | c.4542C>A p.N1514K | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.994); catalogued as COSV101272633; called by muse, mutect2, varscan2
- FBXO31 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100291583; called by muse, mutect2, varscan2
- FCGBP | c.11875C>T p.R3959C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs757705958; called by muse, mutect2, varscan2
- FDCSP | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.576); catalogued as COSV100525838; called by muse, mutect2, varscan2
- FERD3L | c.251G>C p.R84T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as COSV99285060; called by muse, mutect2, varscan2
- FRYL | c.4864C>G p.L1622V | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99977867; called by muse, mutect2, varscan2
- FSCB | c.1577A>T p.Q526L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV100469744; called by muse, mutect2, varscan2
- GALNT3 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV101204998; called by muse, mutect2, varscan2
- GCN1 | c.3877A>T p.N1293Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV100325866; called by muse, mutect2, varscan2
- GCN1 | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100325867; called by muse, mutect2, varscan2
- GGA3 | c.1456A>G p.T486A (on ENST00000537686 / NM_138619.4; = p.T453A on NM_014001.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99822284; called by muse, varscan2
- GLI3 | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV101230008; called by muse, mutect2, varscan2
- GPATCH2 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100861423; called by muse, mutect2, varscan2
- GPC6 | c.1569C>A p.D523E | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV100989861, COSV100990054; called by muse, mutect2, varscan2
- GREM2 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100547929; called by muse, mutect2, varscan2
- GRM1 | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as COSV51234199, COSV99268500; called by muse, mutect2, varscan2
- HCRTR1 | c.1149C>A p.C383* | Nonsense Mutation (SNP) | VAF 75/234 reads (32%) | catalogued as rs75004619, COSV65483796; called by muse, mutect2, varscan2
- HEPHL1 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373413432; called by muse, mutect2, varscan2
- HEPHL1 | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.264); catalogued as COSV100244272; called by muse, mutect2, varscan2
- HTRA2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.326); catalogued as rs1398042174, COSV99239879; called by muse, mutect2, varscan2
- HYKK | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as COSV101195105; called by muse, mutect2, varscan2
- ID3 | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV101000793; called by muse, mutect2, varscan2
- IKZF4 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV100009298; called by muse, mutect2, varscan2
- IL1RL1 | c.1394C>A p.A465D | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99294444; called by muse, mutect2, varscan2
- IQGAP3 | c.2246A>T p.K749M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100752311; called by muse, mutect2, varscan2
- KCNF1 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99705847; called by muse, mutect2, varscan2
- KCNT1 | c.1019C>T p.S340L (on ENST00000488444; = p.S359L on NM_020822.3) | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99706511; called by muse, mutect2, varscan2
- KDELR3 | c.366_369del p.F122Lfs*15 | Frame Shift Del (DEL) | VAF 109/352 reads (31%) | catalogued as rs753780926; called by mutect2, pindel, varscan2
- KDM3A | c.1655A>T p.D552V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.829); catalogued as COSV100460852; called by muse, mutect2, varscan2
- KLF7 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100519345; called by muse, mutect2, varscan2
- LMNTD1 | c.1014T>A p.Y338* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99280217; called by muse, mutect2, varscan2
- LONP2 | c.2105G>T p.S702I | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99589462; called by muse, mutect2, varscan2
- LRFN2 | c.486T>A p.H162Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100599850; called by muse, mutect2, varscan2
- LRIT3 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016359; called by muse, mutect2, varscan2
- LRRC6 | c.47A>T p.N16I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778465163, COSV99138447; called by muse, mutect2, varscan2
- LRRC7 | c.3946A>G p.I1316V (on ENST00000651989 / NM_001370785.2; = p.I1283V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99229191; called by muse, mutect2, varscan2
- LRRIQ1 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV101280681; called by muse, mutect2, varscan2
- LYPD3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs769104790, COSV99747207; called by muse, mutect2, varscan2
- MARCO | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59052592; called by muse, mutect2, varscan2
- MMP8 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99368777; called by muse, varscan2
- MPP2 | c.853A>G p.I285V (on ENST00000461854 / NM_001278372.2; = p.I261V on NM_005374.5) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.447); catalogued as COSV99290762; called by muse, mutect2, varscan2
- MRPS28 | c.45T>G p.H15Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.025); catalogued as COSV99399056; called by muse, mutect2, varscan2
- MSLN | c.583C>A p.R195S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.308); catalogued as COSV99558619; called by muse, mutect2, varscan2
- MTA2 | c.1692+2_1692+3del p.X564_splice | Splice Site (DEL) | VAF 38/181 reads (21%) | catalogued as rs778531730; called by pindel, varscan2
- MTMR4 | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100051367; called by muse, mutect2
- MUC16 | c.43067C>G p.A14356G | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.914); catalogued as COSV101109890, COSV101110050; called by muse, mutect2, varscan2
- MUC16 | c.14078C>G p.P4693R | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV101201168; called by muse, mutect2, varscan2
- MUL1 | c.564G>C p.M188I | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99939441; called by muse, mutect2, varscan2
- MYLK | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100659508; called by muse, mutect2, varscan2
- MYO18B | c.1990G>C p.A664P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100124897, COSV100125354; called by muse, mutect2, varscan2
- MYO6 | c.3392A>G p.K1131R (on ENST00000369981; = p.K1121R on NM_004999.4) | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV100889407; called by muse, mutect2, varscan2
- MYT1L | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV101221306; called by muse, mutect2, varscan2
- NCOR1 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99251664; called by muse, mutect2, varscan2
- NEGR1 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.629); catalogued as COSV60870467; called by muse, mutect2, varscan2
- NFXL1 | c.1663A>G p.S555G | Missense Mutation (SNP) | VAF 74/351 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs200870112, COSV100216987; called by muse, mutect2, varscan2
- NOL6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV99955125; called by muse, mutect2, varscan2
- NRXN1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs202244228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NVL | c.2011A>G p.K671E | Missense Mutation (SNP) | VAF 96/188 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs967421031, COSV99895009; called by muse, mutect2, varscan2
- NXT1 | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99656408; called by muse, mutect2, varscan2
- ONECUT1 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100009400; called by muse, mutect2, varscan2
- OR10G8 | c.571A>C p.T191P | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101461871; called by muse, mutect2, varscan2
- OR11H1 | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV53272104, COSV99421955; called by mutect2, varscan2
- OR4F21 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1458880768; called by mutect2, varscan2
- OR4K13 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100237641, COSV59859632; called by muse, mutect2, varscan2
- OR4K14 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100520508; called by muse, mutect2, varscan2
- OR4Q3 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV100057301, COSV59180746; called by muse, mutect2, varscan2
- OR5D18 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100450492, COSV100450953; called by muse, mutect2, varscan2
- OR6X1 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100020649; called by muse, mutect2, varscan2
- OR8I2 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100136236; called by muse, mutect2, varscan2
- OTOA | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99625554; called by muse, mutect2, varscan2
- OTOGL | c.4597C>A p.P1533T (on ENST00000547103; = p.P1524T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100087762; called by muse, mutect2
- OTOGL | c.4598C>A p.P1533H (on ENST00000547103; = p.P1524H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087765; called by muse, mutect2
- OTULIN | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV99420002; called by muse, mutect2, varscan2
- P2RY14 | c.519A>G p.I173M | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV99854360; called by muse, mutect2, varscan2
- P3H2 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV100078286; called by muse, mutect2, varscan2
- P4HB | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs773105281, COSV100515906; called by muse, mutect2, varscan2
- PAPPA2 | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs745943681, COSV100867049; called by muse, mutect2, varscan2
- PAX7 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100946944; called by muse, mutect2, varscan2
- PCARE | c.1919A>T p.Q640L | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100527813; called by muse, mutect2, varscan2
- PCDH10 | c.1856G>T p.S619I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52093141; called by muse, mutect2, varscan2
- PCDHB13 | c.1312A>T p.T438S | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV53397033; called by muse, mutect2, varscan2
- PDXK | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99376662; called by muse, mutect2, varscan2
- PFAS | c.3902C>A p.A1301D | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100119106; called by muse, mutect2, varscan2
- PKHD1 | c.2726G>C p.R909P | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.593); catalogued as COSV100580721, COSV100584291, COSV61872098; called by muse, mutect2, varscan2
- PLD1 | c.344A>G p.Q115R | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.044); catalogued as COSV100578707; called by muse, mutect2, varscan2
- PLOD3 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56183943, COSV99778244; called by muse, mutect2, varscan2
- PLXNA2 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100885736; called by muse, mutect2
- PNPLA3 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99337279; called by muse, mutect2, varscan2
- POLG | c.2981+1G>C p.X994_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99175014; called by muse, mutect2, varscan2
- POLQ | c.858C>A p.D286E | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99952794; called by muse, mutect2, varscan2
- POTEF | c.2402A>T p.H801L | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100665258; called by muse, mutect2, varscan2
- POU2F2 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100657495; called by muse, mutect2, varscan2
- PRDM9 | c.1426T>C p.F476L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV99691062; called by muse, mutect2, varscan2
- PSG7 | c.656T>A p.I219K | Missense Mutation (SNP) | VAF 205/623 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101343319; called by muse, mutect2, varscan2
- PTAFR | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs765639817, COSV59536388, COSV59538007; called by muse, mutect2, varscan2
- PTGER4 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.166); catalogued as rs1407071127, COSV100201723; called by muse, mutect2, varscan2
- PTPRE | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV99618860; called by muse, mutect2, varscan2
- PYHIN1 | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as COSV100932350, COSV100932403, COSV63721376; called by muse, mutect2, varscan2
- PYY | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748873545, COSV100779011, COSV63972032; called by muse, mutect2, varscan2
- RAP1B | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51670302, COSV99164931; called by muse, mutect2, varscan2
- RAP1GDS1 | c.478G>T p.G160C (on ENST00000408927 / NM_001100427.2; = p.G161C on NM_021159.5) | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99217288; called by muse, mutect2, varscan2
- REPS1 | c.1086A>C p.K362N | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV99238978; called by muse, mutect2, varscan2
- RFC3 | c.918A>T p.*306Cext*19 | Nonstop Mutation (SNP) | VAF 25/43 reads (58%) | catalogued as COSV101447254; called by muse, mutect2, varscan2
- RGS7 | c.336C>A p.T112= | Splice Region (SNP) | VAF 91/217 reads (42%) | catalogued as rs1365647897, COSV100466966; called by muse, mutect2, varscan2
- RHCG | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1199342587, COSV99174218; called by muse, mutect2, varscan2
- RPAP1 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs137979437; called by muse, mutect2, varscan2
- RPS6KA5 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100003072; called by muse, mutect2, varscan2
- RRH | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100496207; called by muse, mutect2, varscan2
- RTP2 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100832996; called by muse, mutect2, varscan2
- RYR2 | c.12542G>T p.G4181V | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100772297, COSV63681976; called by muse, mutect2, varscan2
- SH2D7 | c.898T>C p.S300P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99363438; called by muse, mutect2, varscan2
- SIGLEC5 | c.1171T>C p.W391R | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707833; called by muse, mutect2
- SLC12A3 | c.2348C>A p.S783Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99344625; called by muse, mutect2, varscan2
- SLC24A1 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99978545; called by muse, mutect2, varscan2
- SLC25A38 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372038100; called by muse, mutect2, varscan2
- SLC39A7 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100761849; called by muse, mutect2, varscan2
- SLC5A8 | c.834-2A>T p.X278_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV101610597; called by muse, mutect2, varscan2
- SMC4 | c.2195A>T p.D732V | Missense Mutation (SNP) | VAF 95/513 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs1161073664, COSV100644116; called by muse, mutect2, varscan2
- SMG7 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100750531; called by muse, mutect2, varscan2
- SMR3A | c.362T>A p.V121E | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99895811; called by muse, mutect2, varscan2
- SPOCD1 | c.1784-1G>T p.X595_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99930270; called by muse, mutect2, varscan2
- SPTA1 | c.5932C>A p.Q1978K | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV63751363; called by muse, mutect2
- SPTA1 | c.5930T>C p.L1977P | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100935439; called by muse, mutect2
- SRCAP | c.7802C>G p.S2601C | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); catalogued as COSV52669296; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 77/228 reads (34%) | PolyPhen benign (0.023); catalogued as COSV99336612; called by muse, mutect2, varscan2
- STAM | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101092370; called by muse, mutect2, varscan2
- SYNE1 | c.7052G>T p.S2351I (on ENST00000367255 / NM_182961.4; = p.S2358I on NM_033071.3) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99575611; called by muse, mutect2, varscan2
- TCN2 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV99308755; called by muse, mutect2, varscan2
- TGIF2 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV100872331; called by muse, mutect2, varscan2
- TGM6 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs147591485, COSV99172455; called by muse, mutect2, varscan2
- TKTL2 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54917889; called by muse, mutect2, varscan2
- TKTL2 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749277838, COSV99761683; called by muse, mutect2, varscan2
- TMEM132B | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1342117104, COSV54753211; called by muse, mutect2, varscan2
- TMEM244 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV100933619; called by muse, mutect2, varscan2
- TMPRSS15 | c.1536G>T p.L512F | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV99519028; called by muse, mutect2, varscan2
- TNN | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as rs1309039795, COSV53421169, COSV53432845; called by muse, varscan2
- TPM3 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99666610; called by muse, mutect2, varscan2
- TRANK1 | c.8426A>T p.K2809M | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as rs1378228861, COSV100084464; called by muse, mutect2, varscan2
- TRERF1 | c.2452_2453insCA p.E818Afs*14 | Frame Shift Ins (INS) | VAF 36/138 reads (26%) | catalogued as COSV100551428; called by mutect2, pindel, varscan2
- TRIM55 | c.395T>G p.I132S | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99397170; called by muse, mutect2, varscan2
- TRIML2 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100456279; called by muse, mutect2
- TTC21A | c.2129A>T p.D710V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100087602; called by muse, varscan2
- TTC3 | c.4701A>T p.Q1567H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100695953; called by muse, mutect2, varscan2
- TTLL7 | c.2189A>T p.D730V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99552997; called by muse, mutect2, varscan2
- TTN | c.34021A>G p.R11341G (on ENST00000591111; = p.R10414G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | PolyPhen benign (0.003); catalogued as COSV100626240; called by muse, mutect2, varscan2
- UBA2 | c.1509C>A p.H503Q | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99875753; called by muse, mutect2, varscan2
- UBE2O | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as rs770134258, COSV100084939; called by muse, mutect2, varscan2
- UFSP1 | c.184A>C p.M62L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99574482; called by muse, mutect2, varscan2
- UGGT1 | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99391066; called by muse, mutect2, varscan2
- ULK1 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV100417183; called by muse, mutect2, varscan2
- VAT1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 48/160 reads (30%) | catalogued as COSV99887934; called by muse, mutect2, varscan2
- VENTX | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV100384132; called by muse, mutect2, varscan2
- VGF | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs989757965, COSV99973158; called by muse, mutect2, varscan2
- WDFY3 | c.4971-1G>C p.X1657_splice | Splice Site (SNP) | VAF 70/195 reads (36%) | catalogued as COSV99885193; called by muse, mutect2, varscan2
- WDR13 | c.1228A>G p.S410G | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99489585; called by muse, mutect2, varscan2
- WDR76 | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99776694; called by muse, mutect2, varscan2
- XIRP1 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100453652, COSV100453896; called by muse, mutect2, varscan2
- ZDBF2 | c.3940C>A p.H1314N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100985408; called by muse, mutect2, varscan2
- ZEB2 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV100356693, COSV57952156; called by muse, mutect2, varscan2
- ZFR2 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV99507771; called by muse, mutect2
- ZHX2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100072874, COSV100073762, COSV100074060; called by muse, mutect2, varscan2
- ZNF33A | c.1089A>C p.K363N (on ENST00000458705 / NM_006974.3; = p.K364N on NM_006954.2) | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100276130; called by muse, mutect2, varscan2
- ZNF343 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1018421719, COSV99601617; called by muse, mutect2, varscan2
- ZNF394 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs747627241, COSV100529886, COSV100529927; called by muse, mutect2, varscan2
- ZNF507 | c.621A>T p.R207S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100322059; called by muse, mutect2, varscan2
- ZNF536 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV62825295; called by muse, mutect2, varscan2
- ZNF568 | c.1157G>C p.G386A | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100451400; called by muse, mutect2, varscan2
- ZNF721 | c.1498A>G p.S500G (on ENST00000338977; = p.S512G on NM_133474.4) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.95); catalogued as COSV100167719; called by muse, mutect2, varscan2
- ZNF804A | c.2713G>T p.G905C | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100169710; called by muse, mutect2, varscan2
- ZNF98 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV63334516; called by muse, mutect2, varscan2
- ADAMTS12 | c.4264del p.E1422Sfs*131 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, pindel, varscan2
- BNC2 | c.1499_1502dup p.M501Ifs*6 | Frame Shift Ins (INS) | VAF 48/98 reads (49%) | called by mutect2, pindel, varscan2
- CEP170B | c.414_415del p.P139Ifs*36 (on ENST00000453495; = p.P69Ifs*36 on NM_015005.3) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by pindel, varscan2
- COPS6 | c.575_576del p.T192Rfs*27 | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | called by pindel, varscan2
- CT45A3 | c.550A>C p.K184Q | Missense Mutation (SNP) | VAF 40/514 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CTSS | c.369_370del p.K124Rfs*5 | Frame Shift Del (DEL) | VAF 58/262 reads (22%) | called by pindel, varscan2
- CUL3 | c.1830del p.K610Nfs*44 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | called by mutect2, pindel, varscan2
- EPPK1 | c.1929_1931del p.L644del | In Frame Del (DEL) | VAF 22/46 reads (48%) | called by mutect2, pindel, varscan2
- EZH2 | c.1513_1516del p.K505Yfs*3 (on ENST00000460911 / NM_001203247.2; = p.K510Yfs*3 on NM_004456.5) | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | called by mutect2, pindel, varscan2
- IGKV1-5 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IRX3 | c.1414_1415del p.K472Vfs*33 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.2587del p.Q863Rfs*41 | Frame Shift Del (DEL) | VAF 30/112 reads (27%) | called by mutect2, pindel, varscan2
- MEIOC | c.1580del p.P527Qfs*36 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- MICAL1 | c.1594_1608del p.D532_S536del | In Frame Del (DEL) | VAF 58/215 reads (27%) | called by mutect2, pindel, varscan2
- NXPH1 | c.601del p.V201Lfs*37 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- PCDHGC4 | c.2234del p.P745Lfs*10 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- PTEN | c.507_508del p.Q171Efs*8 | Frame Shift Del (DEL) | VAF 51/139 reads (37%) | called by mutect2, pindel, varscan2
- RPH3A | c.1351_1352del p.L451Afs*10 (on ENST00000389385 / NM_001143854.2; = p.L447Afs*10 on NM_014954.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by pindel, varscan2
- RSPH10B | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC37A1 | c.1114_1117del p.F372Tfs*13 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- SLC6A2 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.344); called by muse, mutect2
- SLCO1A2 | c.169del p.L57* | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- SRCAP | c.7996del p.E2666Sfs*12 | Frame Shift Del (DEL) | VAF 39/86 reads (45%) | called by mutect2, pindel, varscan2
- ST6GALNAC5 | c.592del p.R198Gfs*2 | Frame Shift Del (DEL) | VAF 78/284 reads (27%) | called by mutect2, pindel, varscan2
- TPTE | c.1263T>G p.I421M (on ENST00000618007 / NM_199261.4; = p.I403M on NM_199259.4) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- TRAV21 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- TRIML2 | c.589_590del p.K197Vfs*25 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- USP34 | c.9817_9818del p.Q3273Vfs*2 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- ZNF2 | c.576del p.K193Rfs*41 (on ENST00000611147 / NM_001291605.2; = p.K180Rfs*41 on NM_021088.4) | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by pindel, varscan2
- ZNF676 | c.358G>C p.V120L (on ENST00000650058; = p.V88L on NM_001001411.3) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2
- ABCA2 | c.2718C>A p.I906= (on ENST00000614293; = p.I876= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV99688300; called by muse, mutect2, varscan2
- ABCA8 | c.4566C>A p.A1522= | Silent (SNP) | VAF 72/262 reads (27%) | catalogued as rs372553079, COSV52208152; called by muse, mutect2, varscan2
- ABCF3 | c.1980G>A p.V660= | Silent (SNP) | VAF 78/556 reads (14%) | catalogued as COSV53052827; called by muse, mutect2, varscan2
- ACTR1A | c.690G>A p.K230= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV100883730; called by muse, mutect2, varscan2
- ADAMTS3 | c.2328C>G p.T776= | Silent (SNP) | VAF 107/331 reads (32%) | catalogued as COSV99711862; called by muse, mutect2, varscan2
- ADAMTS7 | c.1932G>A p.L644= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1304034127, COSV101183218; called by muse, mutect2, varscan2
- ADCY2 | c.3111G>T p.L1037= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100603735; called by muse, mutect2, varscan2
- AGAP4 | c.66G>A p.G22= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as rs1437612543; called by muse, mutect2, varscan2
- AHNAK2 | c.6294G>T p.L2098= | Silent (SNP) | VAF 76/324 reads (23%) | catalogued as COSV100318687; called by muse, mutect2
- AHSG | c.462G>C p.P154= | Silent (SNP) | VAF 126/207 reads (61%) | catalogued as COSV56607368, COSV99890291; called by muse, mutect2, varscan2
- AKT1 | c.1425G>T p.S475= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs748603087, COSV100838275; called by muse, mutect2, varscan2
- AMOTL2 | c.1227A>T p.T409= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as COSV99998297; called by muse, mutect2, varscan2
- BBS9 | c.699A>G p.L233= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99629624; called by muse, mutect2, varscan2
- BPIFB4 | c.868C>T p.L290= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as COSV100971635; called by muse, mutect2, varscan2
- C5orf34 | c.150A>C p.P50= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as COSV100175572; called by muse, mutect2, varscan2
- CACHD1 | c.1527C>T p.L509= | Silent (SNP) | VAF 51/153 reads (33%) | catalogued as rs1434118792, COSV99263069; called by muse, mutect2, varscan2
- CALCRL | c.699A>G p.E233= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV101131032; called by muse, mutect2, varscan2
- CBWD1 | c.120C>T p.A40= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as COSV100071194; called by muse, mutect2, varscan2
- CCDC121 | c.222A>G p.E74= | Silent (SNP) | VAF 126/373 reads (34%) | catalogued as rs746632521, COSV99270433; called by muse, mutect2, varscan2
- CCDC54 | c.390A>G p.K130= | Silent (SNP) | VAF 66/155 reads (43%) | catalogued as COSV99660309; called by muse, mutect2, varscan2
- EML2 | c.1167G>T p.R389= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99840369; called by muse, mutect2, varscan2
- ETV7 | c.549C>A p.T183= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1339689988, COSV100339296; called by muse, mutect2, varscan2
- EZHIP | c.195C>T p.A65= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV100539811; called by muse, mutect2, varscan2
- FAT3 | c.13425C>A p.G4475= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99969958; called by muse, mutect2, varscan2
- FRG2 | c.390T>A p.T130= | Silent (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- GABRG2 | c.1059G>A p.L353= (on ENST00000361925 / NM_001375343.1; = p.L313= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100729805; called by muse, mutect2, varscan2
- GPR35 | c.402G>A p.A134= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs777605863, COSV100166644; called by muse, mutect2, varscan2
- GPR45 | c.1041C>A p.P347= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as COSV99307142; called by muse, mutect2, varscan2
- GPR85 | c.723C>A p.A241= | Silent (SNP) | VAF 65/132 reads (49%) | catalogued as rs138737854; called by muse, mutect2, varscan2
- HNF4G | c.789G>A p.R263= (on ENST00000354370 / NM_001330561.2; = p.R310= on NM_004133.5) | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs781717488, COSV100584927; called by muse, mutect2, varscan2
- IFT80 | c.885T>C p.F295= | Silent (SNP) | VAF 47/256 reads (18%) | catalogued as COSV100425079; called by muse, mutect2, varscan2
- IL13RA2 | c.24C>A p.I8= | Silent (SNP) | VAF 70/105 reads (67%) | catalogued as COSV99683311; called by muse, mutect2, varscan2
- ITGA8 | c.1107C>A p.L369= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV100959611; called by muse, mutect2, varscan2
- LHX2 | c.930C>G p.L310= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV101010082; called by muse, mutect2, varscan2
- MAS1L | c.168G>C p.T56= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV101009716, COSV65808436, COSV65808706; called by muse, mutect2, varscan2
- MDH2 | c.573A>T p.R191= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100242786; called by muse, mutect2, varscan2
- MEPE | c.687C>A p.V229= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV100734985; called by muse, mutect2, varscan2
- MUC16 | c.36912C>T p.H12304= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV101201167; called by muse, mutect2, varscan2
- MYH4 | c.3198C>A p.A1066= | Silent (SNP) | VAF 84/175 reads (48%) | catalogued as COSV99702034; called by muse, mutect2, varscan2
- NLGN4X | c.1566G>A p.V522= | Silent (SNP) | VAF 40/60 reads (67%) | catalogued as COSV99323547; called by muse, mutect2, varscan2
- NRXN1 | c.2337G>T p.T779= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100456554, COSV58437958; called by muse, mutect2, varscan2
- OCA2 | c.1050G>A p.V350= | Silent (SNP) | VAF 73/232 reads (31%) | catalogued as COSV100668212; called by muse, mutect2, varscan2
- OR5J2 | c.285T>A p.S95= | Silent (SNP) | VAF 75/195 reads (38%) | catalogued as COSV100399209; called by muse, varscan2
- OR5M3 | c.711C>T p.S237= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs1181394741, COSV100392238, COSV100392656; called by muse, mutect2, varscan2
- OVCH1 | c.1104A>G p.Q368= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100549077; called by muse, mutect2, varscan2
- PAPOLB | c.924T>C p.S308= | Silent (SNP) | VAF 52/162 reads (32%) | catalogued as rs778089778, COSV101271598; called by muse, mutect2, varscan2
- PCDH11Y | c.2181C>T p.V727= (on ENST00000400457 / NM_032973.2; = p.V716= on NM_032971.3) | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as COSV99292457; called by muse, mutect2, varscan2
- PCDH11Y | c.2961C>T p.P987= (on ENST00000400457 / NM_032973.2; = p.P976= on NM_032971.3) | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as COSV99292463; called by muse, mutect2, varscan2
- PIGR | c.1671C>A p.A557= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV100732599; called by muse, mutect2, varscan2
- PIK3CG | c.1341A>G p.A447= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100783104; called by muse, mutect2, varscan2
- PLEC | c.6042G>A p.R2014= (on ENST00000322810 / NM_201380.4; = p.R1904= on NM_000445.5) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100518095; called by muse, mutect2, varscan2
- POM121L12 | c.165G>C p.L55= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs374979505, COSV101374860, COSV68693732; called by muse, mutect2, varscan2
- PPP6R2 | c.2772G>A p.V924= (on ENST00000216061 / NM_001365836.1; = p.V890= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV99324714; called by muse, mutect2, varscan2
- PTGER4 | c.1158G>A p.K386= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100201724; called by muse, mutect2, varscan2
- PTPRN | c.300C>T p.D100= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs770131939, COSV99834250; called by muse, mutect2, varscan2
- RAP1B | c.528C>T p.R176= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV99164934; called by muse, mutect2, varscan2
- RELN | c.8157A>T p.V2719= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs1432672559, COSV100634609; called by muse, mutect2, varscan2
- SEC24B | c.795A>T p.P265= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV54502438, COSV99494174; called by muse, mutect2, varscan2
- SERPINB2 | c.57G>T p.L19= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV100208631; called by muse, mutect2, varscan2
- SGCE | c.243C>T p.H81= (on ENST00000647096; = p.H45= on NM_003919.3) | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as rs1394843820, COSV99722853; called by muse, mutect2, varscan2
- SIPA1L3 | c.24C>A p.P8= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99730159; called by muse, mutect2, varscan2
- SLC2A12 | c.402A>T p.I134= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as COSV99260450; called by muse, mutect2, varscan2
- SLC32A1 | c.1527G>T p.V509= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99462584; called by muse, mutect2, varscan2
- SLC9A3 | c.1983G>A p.L661= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV99376566; called by muse, mutect2, varscan2
- SLCO2A1 | c.333T>A p.G111= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100189261; called by muse, mutect2, varscan2
- TBL1XR1 | c.330T>G p.A110= | Silent (SNP) | VAF 51/237 reads (22%) | catalogued as rs774761056, COSV100763629; called by muse, mutect2, varscan2
- TCHHL1 | c.2634C>A p.P878= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV100916594, COSV64287596; called by muse, mutect2, varscan2
- THSD7B | c.2167C>A p.R723= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV55649817, COSV99757072; called by muse, mutect2, varscan2
- TPCN2 | c.849C>A p.S283= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV53734538, COSV99593855; called by muse, mutect2, varscan2
- TSC22D2 | c.2283G>T p.V761= | Silent (SNP) | VAF 46/265 reads (17%) | catalogued as COSV100721269, COSV100721274; called by muse, mutect2, varscan2
- UACA | c.2394C>T p.R798= | Silent (SNP) | VAF 53/147 reads (36%) | catalogued as COSV100537690; called by muse, mutect2, varscan2
- ZNF92 | c.1059C>T p.F353= (on ENST00000328747 / NM_152626.4; = p.F284= on NM_007139.4) | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100165933, COSV60873934; called by muse, mutect2
- CCNQP1 | n.514G>T | RNA (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- DCHS2 | n.8570C>A | RNA (SNP) | VAF 68/176 reads (39%) | catalogued as COSV100602450; called by muse, mutect2, varscan2
- GCNT2 | c.926-34886_926-34885del | Intron (DEL) | VAF 61/276 reads (22%) | catalogued as rs750203095; called by pindel, varscan2
- H3-3B | chr17:75784728 C>T | 5'Flank (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53143945, COSV99505490; called by muse, mutect2
- MORF4 | n.701C>A | RNA (SNP) | VAF 115/280 reads (41%) | called by muse, mutect2, varscan2
- NT5C1B-RDH14 | c.*14G>A | 3'UTR (SNP) | VAF 60/188 reads (32%) | catalogued as COSV101173362; called by muse, mutect2, varscan2
- PARGP1 | n.1208A>T | RNA (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81165862 del G | 3'Flank (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- TXLNGY | chrY:19589564 G>T | 5'Flank (SNP) | VAF 51/111 reads (46%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2745C>A | Intron (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100268332; called by muse, mutect2, varscan2
